Somatic mutation profile of tumor specimen C3L-05556-01 (aliquot CPT0373460006) from CPTAC case C3L-05556, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.1 years (25,964 days).
Specimen C3L-05556-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4364a59d-3bf3-4366-bc5b-ca7829de7bea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05556-31 (Blood Derived Normal), aliquot CPT0374710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04989eb-38fb-4594-a894-dd2d03bf1c90

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Splice Site 2, Splice Region 2, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOT11 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs893744944; called by muse, mutect2, varscan2
- ARHGEF10 | c.1514C>T p.S505L (on ENST00000398564; = p.S480L on NM_014629.4) | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201240439, COSV50646851; called by muse, mutect2, varscan2
- CSMD1 | c.4429G>A p.E1477K (on ENST00000520002; = p.E1476K on NM_033225.6) | Missense Mutation (SNP) | VAF 101/330 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59326169; called by muse, mutect2, varscan2
- ELF3 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 98/537 reads (18%) | catalogued as COSV62841040; called by muse, mutect2, varscan2
- FMO2 | c.322-1G>A p.X108_splice | Splice Site (SNP) | VAF 66/522 reads (13%) | catalogued as COSV99268923; called by muse, mutect2, varscan2
- LILRB4 | c.1235C>T p.T412I (on ENST00000391733 / NM_001278428.3; = p.T411I on NM_001278426.3) | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs773259841; called by muse, mutect2, varscan2
- PATE3 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs1046892025; called by muse, mutect2, varscan2
- TTLL11 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs779819812, COSV100388854; called by muse, mutect2, varscan2
- TUBB | c.1321_1332del p.E441_A444del | In Frame Del (DEL) | VAF 80/559 reads (14%) | catalogued as rs747584215; called by mutect2, varscan2
- ARHGAP36 | c.1488T>C p.G496= | Splice Region (SNP) | VAF 74/257 reads (29%) | called by muse, mutect2, varscan2
- CDH10 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 92/261 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CFAP65 | c.2796dup p.L933Afs*87 | Frame Shift Ins (INS) | VAF 92/335 reads (27%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.2296_2313dup p.G766_F771dup | In Frame Ins (INS) | VAF 34/151 reads (23%) | called by mutect2, varscan2
- DCHS1 | c.5545A>G p.N1849D | Missense Mutation (SNP) | VAF 136/428 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FSIP2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IPO7 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KLHDC7A | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 147/443 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- KMT2D | c.5190G>T p.V1730= | Splice Region (SNP) | VAF 65/201 reads (32%) | called by muse, mutect2, varscan2
- NEXMIF | c.3904A>C p.T1302P | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- NTM | c.601T>G p.C201G | Missense Mutation (SNP) | VAF 127/358 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIBF1 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PTPRC | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SELENOT | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 85/288 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SNX16 | c.862A>C p.T288P | Missense Mutation (SNP) | VAF 79/444 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYK2 | c.2466+1G>A p.X822_splice | Splice Site (SNP) | VAF 102/367 reads (28%) | called by muse, mutect2, varscan2
- C16orf54 | c.159T>C p.A53= | Silent (SNP) | VAF 177/483 reads (37%) | called by muse, mutect2, varscan2
- DIAPH3 | c.1980T>G p.T660= (on ENST00000400324 / NM_001042517.2; = p.T397= on NM_030932.3) | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV99932552; called by muse, mutect2, varscan2
- KRT33A | c.1116C>T p.C372= | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as rs367601440, COSV50367229; called by muse, mutect2, varscan2
- OPRK1 | c.867C>A p.P289= | Silent (SNP) | VAF 146/449 reads (33%) | catalogued as COSV99654168; called by muse, mutect2, varscan2
- OR2A12 | c.609G>A p.A203= | Silent (SNP) | VAF 114/476 reads (24%) | catalogued as rs539744343, COSV68821029; called by muse, mutect2, varscan2
- PDHA2 | c.399C>T p.L133= | Silent (SNP) | VAF 101/400 reads (25%) | catalogued as rs766615895, COSV54777843, COSV54778645; called by muse, mutect2, varscan2
- RAD54L | c.1602T>C p.R534= | Silent (SNP) | VAF 63/188 reads (34%) | called by muse, mutect2, varscan2
- SAPCD2 | c.345G>A p.Q115= | Silent (SNP) | VAF 142/367 reads (39%) | called by muse, varscan2
- SMPDL3B | c.861T>C p.Y287= | Silent (SNP) | VAF 97/272 reads (36%) | catalogued as rs767587874; called by muse, mutect2, varscan2
